Gene-level copy-number profile of tumor specimen TCGA-44-2656-01A from TCGA case TCGA-44-2656, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.6 years (21,766 days).
Specimen TCGA-44-2656-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.7bbc5291-ea7a-4ce9-baa4-7a30a079eace.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-2656-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (3 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/97f326f4-6ffb-42d4-8bce-5f6ca1d282c5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,516; copy number 2: 22,087; copy number 3: 17,912; copy number 4: 10,012; copy number 5: 5,742; copy number 6: 413; copy number 7: 2,138.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-2656-01A-02D-A273-01): tumor purity 0.32, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,293 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr4:136,355,110–190,092,279, 764 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–39,274,528, 610 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:70,972–65,770,810, 1,216 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:46,028,804–112,148,825, 1,015 genes, copy number 7 (broad region; genes not listed).
- chr8:113,438,334–145,066,685, 513 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr11:85,694,224–135,075,908, 1,016 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:49,361,150–70,180,044, 555 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,516. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
